Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A1ZC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A1ZC-06A (Metastatic).

Prof.Dr

ICB-0-3

Melanoma, NOS 8720/3

Site: skin, NOS C44.9

on 7/24/11

Patient: XXXX
geb. *** **

Datum:

Translation of pathology report F

Sample

Gross Pathology

Cryofixed specimen with a weight of

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 90 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine. There is a high nucleo/cytoplasmatic ratio. The mitotic count is 23 mitoses per square millimetre. The tumor cells have a middle sized cytoplasm. The tumor shows a sheet like growth pattern. Lymphocytic infiltrates compound approx. 10 percent of the tissue cells. Approx. 5 percent of the tumor cells are apoptotic.

Diagnosis: Parts of a malignat tumor, consistent with a metastasis of a melanoma.

Dr.

CRCF Site = skin

Primary Tumor Site Discrepancy not checked on path		

Source: NCI Genomic Data Commons file 6a483fb6-90ca-404b-a2d2-6d45bad1a883 (TCGA-FS-A1ZC.4A08AB50-3D1F-4E95-BD50-F83E4053E05E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).